Somatic mutation profile of tumor specimen TCGA-MB-A5Y8-01A (aliquot TCGA-MB-A5Y8-01A-11D-A29N-09) from TCGA case TCGA-MB-A5Y8, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 60.5 years (22,115 days).
Specimen TCGA-MB-A5Y8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0938f069-f8f9-4be8-a198-ebb446e066af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MB-A5Y8-10A (Blood Derived Normal), aliquot TCGA-MB-A5Y8-10A-01D-A29N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24accbe2-655b-4c38-80f2-ea68368883f3

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 16, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD27 | c.275T>C p.V92A | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.853); catalogued as COSV100043154; called by muse, mutect2, varscan2
- ARMH3 | c.628G>C p.V210L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs1333213429, COSV100899046; called by muse, mutect2, varscan2
- CDK4 | c.43G>C p.G15R | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99225963, COSV99226121; called by muse, mutect2, varscan2
- CYP3A7 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV100312889; called by muse, mutect2, varscan2
- DARS1 | c.54G>T p.M18I | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99927920; called by muse, mutect2, varscan2
- DISP2 | c.2744C>T p.P915L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs559188294, COSV51116419, COSV99140517; called by muse, mutect2, varscan2
- IL13RA2 | c.434G>A p.C145Y | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782363407, COSV99683364; called by muse, mutect2, varscan2
- MAP7D1 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60215658; called by muse, mutect2, varscan2
- OCIAD1 | c.137G>C p.R46T | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99971283; called by muse, mutect2, varscan2
- OR13C5 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.053); catalogued as COSV101053172; called by muse, varscan2
- PIGC | c.440A>T p.D147V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as COSV99278385; called by muse, mutect2, varscan2
- REPS1 | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as COSV99239028; called by muse, mutect2, varscan2
- SUGP2 | c.710C>G p.A237G | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV100432330; called by muse, mutect2, varscan2
- TEX14 | c.1679T>C p.I560T (on ENST00000240361 / NM_001201457.2; = p.I554T on NM_031272.5) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV99543627; called by muse, mutect2, varscan2
- TGM1 | c.1202T>G p.F401C | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99253234; called by muse, mutect2, varscan2
- NHS | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP54 | c.6693C>T p.N2231= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs932205531, COSV100733330; called by muse, mutect2, varscan2
- DLX1 | c.633C>G p.P211= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs200336628, COSV100543313; called by muse, mutect2, varscan2
- ETV5 | c.489C>T p.A163= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1302107892, COSV100112581; called by muse, mutect2, varscan2
- PCDH15 | c.339C>T p.S113= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs772070013, COSV57411774; called by muse, mutect2, varscan2
- SERPINB9 | c.801T>C p.V267= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as COSV101046739; called by muse, mutect2, varscan2
